CCDI case PBCVHI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/207249ba-b057-42e5-a6ef-0b7fe6d26742

Demographics
Sex at birth: male.

Biospecimens (4 samples)
- Sample 0E0YBE: Tissue type: Tumor; Specimen type: Solid Tissue.
- Samples 0E0YCT, 0E2B28 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0E0YD2: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
